Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-6608, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-6608-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Sigmoid colon mass

PROCEDURE: Sigmoid colon resection

SPECIFIC CLINICAL QUESTION: Not answered

OUTSIDE TISSUE DIAGNOSIS: Not answered

PRIOR MALIGNANCY: Not answered

CHEMOTHERAPY: Not answered

ORGAN TRANSPLANT: Not answered

IMMUNOSUPPRESSION: Not answered

OTHER DISEASES: Not answered

FINAL DIAGNOSIS:

Collection Date: [REDACTED]

SIGMOID COLON, SEGMENTAL COLECTOMY -

- A. ULCERATED, POLYPOID, INVASIVE, MODERATELY DIFFERENTIATED, COLONIC ADENOCARCINOMA, 3 CM, PRESENT IN THE SIGMOID COLON 3 CM FROM THE PROXIMAL AND 5.5 CM FROM THE DISTAL RESECTION MARGINS.
- B. CARCINOMA INVADES DEEPLY INTO, BUT NOT THROUGH THE MUSCULARIS PROPRIA.
- C. PRESUMED ANGIOLYMPHATIC INVASION (see diagnosis G).
- D. ONE SMALL TUBULAR ADENOMA.
- E. ALL SURGICAL RESECTION MARGINS, SUBSEROUSAL AND SEROUSAL SURFACE ARE BENIGN.
- F. NON-NEOPLASTIC COLONIC MUCOSA WITH NO SIGNIFICANT HISTOPATHOLOGIC ABNORMALITY.
- G. METASTATIC COLONIC ADENOCARCINOMA IS PRESENT AND LARGELY REPLACES TWO OF TWELVE (2/12) REGIONAL LYMPH NODES. THE LARGER METASTATIC FOCUS MEASURES 0.4 CM. NO EXTRACAPSULAR EXTENSION IS IDENTIFIED.
- H. TNM PATHOLOGIC STAGE: T2 N1 MX (see synopsis).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY COLON, RECTAL, APPENDIX TUMORS

SPECIMEN TYPE: Sigmoidectomy
SPECIMEN LENGTH: 11.5 cm
TUMOR SITE: Sigmoid colon
TUMOR CONFIGURATION: Exophytic (polypoid)
TUMOR SIZE: Greatest dimension: 3 cm
Additional dimensions: 3 x 1.7 cm
INTACTNESS OF MESORECTUM: Not applicable
HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: Low-grade (well to moderately differentiated)
PATHOLOGIC STAGING (pTNM): pT2

pN1
Number of nodes examined: 12
Number of nodes involved: 2
pMX

Treatment: Untreated

MARGINS:

Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Circumferential (radial) margin - Not applicable
Mesenteric margin uninvolved by invasive carcinoma
If all margins uninvolved by invasive carcinoma: distance of invasive carcinoma from closest margin: 30 mm
Margin: Proximal

ANGIOLYMPHATIC INVASION:

Present

PERINEURAL INVASION:

Absent

TUMOR BORDER CONFIGURATION:

Infiltrating

ADDITIONAL TUMOR CHARACTERISTICS:

None

ADDITIONAL PATH FINDINGS (check all that apply):

Adenoma(s)

Source: NCI Genomic Data Commons file f1cc4fc3-0b87-40aa-846b-8b4c59fcc0f6 (TCGA-AZ-6608.75A5B0F7-23F0-41DE-B863-9029A57FF12D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).